Somatic mutation profile of cancer-model specimen HCM-BROD-1123-C71-85A (3D Neurosphere; aliquot HCM-BROD-1123-C71-85A-01D-A881-36), derived from the recurrence tumor of HCMI case HCM-BROD-1123-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.2 years (17,954 days).
Specimen HCM-BROD-1123-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba35379b-c9fd-43ba-b6e3-7d75e91f9cd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-1123-C71-10A (Blood Derived Normal), aliquot HCM-BROD-1123-C71-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36cc2514-87f7-404a-9592-0743309e9b50

The open-access MAF lists 1,561 somatic variants for this specimen: 973 protein-altering or splice-affecting, 517 silent, 71 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 884, Silent 517, Intron 46, Nonsense Mutation 38, Splice Site 23, Splice Region 17, Frame Shift Del 10, 3'UTR 9, 5'UTR 6, RNA 5, 5'Flank 4, 3'Flank 1.

Variants (750 of 1,561; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGB3 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 67/165 reads (41%) | catalogued as rs764742792, CM050554, COSV60684823; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 233/548 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 20/418 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1251357502; called by muse, mutect2
- ABHD14A-ACY1 | c.1154G>A p.W385* | Nonsense Mutation (SNP) | VAF 178/477 reads (37%) | catalogued as rs758418338; called by muse, mutect2, varscan2
- ACAD9 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 252/587 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs781653464; called by muse, mutect2, varscan2
- ADAM33 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 26/655 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as rs1032547966; called by muse, mutect2
- ADAMTS16 | c.3470G>A p.G1157D | Missense Mutation (SNP) | VAF 38/908 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV56978834; called by muse, mutect2
- ADGRE2 | c.1079G>A p.G360D | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.275); catalogued as COSV100216302; called by muse, mutect2, varscan2
- ADNP2 | c.1787G>A p.G596D | Missense Mutation (SNP) | VAF 34/746 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV100081332; called by muse, mutect2
- AGRN | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 235/647 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs200974261; called by muse, mutect2, varscan2
- AKAP8 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 180/265 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54104898; called by muse, mutect2, varscan2
- ALG1 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 18/478 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV99275664; called by muse, mutect2
- AMPH | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 131/442 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV57759094; called by muse, mutect2, varscan2
- ANKRD11 | c.6916C>T p.P2306S | Missense Mutation (SNP) | VAF 22/672 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as rs1228597465; called by muse, mutect2
- ANKRD13A | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 168/455 reads (37%) | catalogued as rs1182929875, COSV99923969; called by muse, mutect2, varscan2
- ANKRD27 | c.2575G>A p.V859I | Missense Mutation (SNP) | VAF 97/355 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs769389334; called by muse, mutect2, varscan2
- ANO8 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50180059, COSV50181421; called by muse, mutect2
- APC2 | c.4786G>A p.A1596T | Missense Mutation (SNP) | VAF 40/822 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1460415485; called by muse, mutect2
- ARAP3 | c.4027C>T p.R1343C | Missense Mutation (SNP) | VAF 247/517 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs763833196; called by muse, mutect2, varscan2
- ARHGAP11A | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 34/778 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1396858491; called by muse, mutect2
- ARHGAP25 | c.62-6C>T | Splice Region (SNP) | VAF 30/432 reads (7%) | catalogued as COSV54905227; called by muse, mutect2
- ARHGAP27 | c.1972G>A p.V658M (on ENST00000428638 / NM_001282290.1; = p.V317M on NM_199282.3) | Missense Mutation (SNP) | VAF 99/557 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs368827618; called by muse, mutect2, varscan2
- ARL6IP4 | c.1087G>A p.A363T (on ENST00000315580 / NM_018694.3; = p.A344T on NM_016638.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/718 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); catalogued as rs796530509; called by muse, mutect2
- ARV1 | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV59617563; called by muse, mutect2, varscan2
- ASXL1 | c.2518C>T p.P840S | Missense Mutation (SNP) | VAF 21/497 reads (4%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.351); catalogued as COSV60124574; called by muse, mutect2
- ATF6B | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 34/666 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs904077443; called by muse, mutect2
- ATG2A | c.3155T>C p.I1052T | Missense Mutation (SNP) | VAF 42/674 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV65966033; called by muse, mutect2
- ATP10D | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 34/648 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as COSV99905652; called by muse, mutect2
- ATP11B | c.2836C>T p.L946F | Missense Mutation (SNP) | VAF 94/303 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs774685627; called by muse, mutect2, varscan2
- ATP13A5 | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 118/348 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100664965; called by muse, mutect2, varscan2
- ATXN10 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 22/422 reads (5%) | catalogued as rs1461354451; called by muse, mutect2
- BCL9L | c.1967C>T p.T656I | Missense Mutation (SNP) | VAF 210/579 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV52689660; called by muse, mutect2, varscan2
- BEGAIN | c.1723G>A p.G575R | Missense Mutation (SNP) | VAF 28/469 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1031054741; called by muse, mutect2
- BICD1 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 30/445 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55677977; called by muse, mutect2
- BLID | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.278); catalogued as COSV101601740, COSV73340316; called by muse, mutect2
- BRCA2 | c.2711G>A p.G904E | Missense Mutation (SNP) | VAF 21/370 reads (6%) | SIFT tolerated (0.88); PolyPhen benign (0.072); catalogued as rs1555282808; ClinVar: uncertain significance; called by muse, mutect2
- BRCA2 | c.7834C>T p.P2612S | Missense Mutation (SNP) | VAF 114/312 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs771981392; called by muse, mutect2, varscan2
- BTAF1 | c.5218G>A p.A1740T | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1437161763; called by muse, mutect2, varscan2
- BTBD8 | c.2141G>A p.G714E (on ENST00000636805 / NM_001376131.1; = p.G201E on NM_015237.4) | Missense Mutation (SNP) | VAF 32/566 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs1452043414; called by muse, mutect2
- BTBD9 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 108/293 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1278680975, COSV100022936; called by muse, mutect2, varscan2
- BX248415.1 | n.425G>A | Splice Region (SNP) | VAF 170/340 reads (50%) | catalogued as rs757684781; called by muse, mutect2, varscan2
- C6orf226 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 31/912 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59034410; called by muse, mutect2
- CABP1 | c.925G>A p.D309N (on ENST00000316803 / NM_001033677.1; = p.D106N on NM_004276.5) | Missense Mutation (SNP) | VAF 30/582 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as rs1566000772; called by muse, mutect2
- CACNA1B | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 37/1132 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1311524977; called by muse, mutect2
- CACNA1B | c.6130C>T p.P2044S | Missense Mutation (SNP) | VAF 55/1082 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs921419441; called by muse, mutect2
- CACNB1 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 28/536 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV59999890; called by muse, mutect2
- CAMKK2 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 38/736 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.051); catalogued as rs1419461541; called by muse, mutect2
- CAPN15 | c.2969A>T p.E990V | Missense Mutation (SNP) | VAF 307/648 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769060825; called by muse, mutect2, varscan2
- CAPSL | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 157/449 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV101274207; called by muse, mutect2, varscan2
- CD19 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 20/526 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs1167037034; called by muse, mutect2
- CDC42EP4 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 260/725 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs150232785; called by muse, mutect2, varscan2
- CDH19 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 250/516 reads (48%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs141432968, COSV50956344; called by muse, mutect2, varscan2
- CDK4 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 179/391 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV56983667; called by muse, mutect2, varscan2
- CEBPZ | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 40/572 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV50018046; called by muse, mutect2
- CELSR3 | c.6958G>A p.V2320M | Missense Mutation (SNP) | VAF 102/251 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1026169257; called by muse, mutect2, varscan2
- CEP85 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 273/576 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.431); catalogued as rs567012962, COSV99432669; called by muse, mutect2, varscan2
- CES5A | c.1497G>A p.G499= (on ENST00000290567 / NM_001143685.2; = p.G449= on NM_145024.3) | Splice Region (SNP) | VAF 21/424 reads (5%) | catalogued as COSV51869169; called by muse, mutect2
- CETP | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 210/492 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs765669263; called by muse, mutect2, varscan2
- CFAP47 | c.9361G>A p.E3121K | Missense Mutation (SNP) | VAF 134/143 reads (94%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV66216932; called by muse, mutect2, varscan2
- CFAP65 | c.4858G>A p.A1620T | Missense Mutation (SNP) | VAF 32/590 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV58566232; called by muse, mutect2
- CLEC5A | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 26/703 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69396684; called by muse, mutect2
- CNGB1 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 273/594 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.017); catalogued as rs765835118, COSV51900464; called by muse, mutect2
- CNTNAP5 | c.2660C>T p.S887F | Missense Mutation (SNP) | VAF 26/558 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV70477774; called by muse, mutect2
- COL22A1 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 202/548 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV57331182; called by muse, mutect2, varscan2
- COX7B2 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 118/324 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs768732297; called by muse, mutect2, varscan2
- CRACD | c.2690G>A p.G897D | Missense Mutation (SNP) | VAF 218/674 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.387); catalogued as rs745577518; called by muse, mutect2, varscan2
- CREBBP | c.562C>T p.L188F | Missense Mutation (SNP) | VAF 25/606 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1181685618; called by muse, mutect2
- CRISP3 | c.614+1G>A p.X205_splice (on ENST00000371159 / NM_001368123.1; = p.X187_splice on NM_006061.4) | Splice Site (SNP) | VAF 98/207 reads (47%) | catalogued as rs762333204, COSV53819771, COSV53821819; called by muse, mutect2, varscan2
- CYLC2 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.7); catalogued as rs762306424, COSV100872558, COSV66337213; called by muse, mutect2, varscan2
- CYP2R1 | c.1457G>A p.G486D | Missense Mutation (SNP) | VAF 22/448 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58128307; called by muse, mutect2
- DHX15 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 15/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100391015, COSV61026248; called by muse, mutect2
- DHX36 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 96/241 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV57675937; called by muse, mutect2, varscan2
- DNAH14 | c.2137G>A p.E713K (on ENST00000445597; = p.E742K on NM_001367479.1) | Missense Mutation (SNP) | VAF 24/365 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV70541169; called by muse, mutect2
- DOCK8 | c.895-1G>A p.X299_splice | Splice Site (SNP) | VAF 67/207 reads (32%) | catalogued as COSV66635088; called by muse, mutect2, varscan2
- DRD4 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 32/708 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1323034674; called by muse, mutect2
- DSE | c.2097G>A p.W699* | Nonsense Mutation (SNP) | VAF 245/556 reads (44%) | catalogued as rs1241467661; called by muse, mutect2, varscan2
- DSP | c.7790C>T p.S2597F | Missense Mutation (SNP) | VAF 183/439 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV65793967; called by muse, mutect2, varscan2
- DYNC1I1 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 124/518 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.044); catalogued as rs201114371, COSV61456326; called by muse, mutect2, varscan2
- ECM2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 321/815 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1400876397; called by muse, mutect2, varscan2
- EFTUD2 | c.2816G>A p.R939H | Missense Mutation (SNP) | VAF 157/331 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763935473, COSV99493825; called by muse, mutect2, varscan2
- EGFR | c.827A>T p.Q276L | Missense Mutation (SNP) | VAF 353/875 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV99294781; called by muse, mutect2, varscan2
- EIF4G1 | c.4036C>T p.P1346S (on ENST00000346169 / NM_198241.3; = p.P1151S on NM_004953.5) | Missense Mutation (SNP) | VAF 19/515 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100072419; called by muse, mutect2
- EIF4G3 | c.3319C>T p.P1107S | Missense Mutation (SNP) | VAF 26/454 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99944226; called by muse, mutect2
- ELAPOR2 | c.2663G>A p.G888E (on ENST00000450689 / NM_001142749.3; = p.G721E on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/432 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs771865743, COSV99789293; called by muse, mutect2, varscan2
- ENOX2 | c.1231G>A p.A411T (on ENST00000338144 / NM_001382520.1; = p.A382T on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV57658287; called by muse, mutect2
- ENPP2 | c.1399G>A p.G467R (on ENST00000075322 / NM_001040092.3; = p.G519R on NM_006209.5) | Missense Mutation (SNP) | VAF 126/329 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs771458355; called by muse, mutect2, varscan2
- EPHA4 | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 129/237 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.698); catalogued as rs371177966; called by muse, mutect2, varscan2
- EPHB6 | c.2320G>A p.V774M | Missense Mutation (SNP) | VAF 324/1059 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as rs1426321238; called by muse, mutect2, varscan2
- ERBB2 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 234/636 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54068571; called by muse, mutect2, varscan2
- EVPLL | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 206/404 reads (51%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as rs755615782; called by muse, mutect2, varscan2
- FAM234A | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 23/446 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0.014); catalogued as rs1049196082, COSV51451514; called by muse, mutect2
- FAT1 | c.5257G>A p.V1753I | Missense Mutation (SNP) | VAF 23/658 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.136); catalogued as COSV71676374; called by muse, mutect2
- FBXL6 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 35/880 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs1554853440; called by muse, mutect2
- FCRLB | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 218/539 reads (40%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs753631635; called by muse, mutect2, varscan2
- FES | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 28/622 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0.079); catalogued as rs1443345664; called by muse, mutect2
- FIGLA | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 19/368 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1442566305; called by muse, mutect2
- FLNB | c.6860C>T p.A2287V | Missense Mutation (SNP) | VAF 23/437 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55885809; called by muse, mutect2
- FMN2 | c.3793C>T p.P1265S | Missense Mutation (SNP) | VAF 205/540 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100142687; called by muse, mutect2, varscan2
- FOS | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 21/383 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs1270352847; called by muse, mutect2
- FRY | c.7465G>A p.D2489N | Missense Mutation (SNP) | VAF 222/564 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV66567170; called by muse, mutect2, varscan2
- FSIP1 | c.328del p.E110Nfs*2 | Frame Shift Del (DEL) | VAF 66/214 reads (31%) | catalogued as COSV63224363; called by mutect2, pindel, varscan2
- FSIP2 | c.9721G>A p.V3241I | Missense Mutation (SNP) | VAF 182/369 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1559030176; called by muse, mutect2, varscan2
- GALM | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV55371227; called by muse, mutect2
- GBE1 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 93/269 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1192634867; called by muse, mutect2, varscan2
- GC | c.58+1G>A p.X20_splice | Splice Site (SNP) | VAF 16/320 reads (5%) | catalogued as rs1454799901; called by muse, mutect2
- GIPC1 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 24/508 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1311846207; called by muse, mutect2
- GJA8 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 279/586 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs140686949; called by muse, mutect2, varscan2
- GLUD2 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 44/529 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60152156; called by muse, mutect2
- GPR146 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 45/1136 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1055118120; called by muse, mutect2
- GRIN3B | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 65/862 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.446); catalogued as rs1323936348; called by muse, mutect2
- GRXCR1 | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67671792; called by muse, mutect2
- GYG2 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 58/588 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.264); catalogued as rs907298242; called by muse, mutect2
- H1-2 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 160/356 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as rs201575995, COSV59190824; called by muse, varscan2
- H2AB1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 44/628 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100371834; called by muse, mutect2
- HAO2 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 138/328 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216284074, COSV58040158; called by muse, mutect2, varscan2
- HECW1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 250/937 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.036); catalogued as rs777589869; called by muse, mutect2, varscan2
- HERC2 | c.4372G>A p.V1458I | Missense Mutation (SNP) | VAF 116/367 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.054); catalogued as rs1297062378; called by muse, mutect2, varscan2
- HIF1A | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 185/229 reads (81%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1566573924; called by muse, mutect2, varscan2
- HIP1 | c.2839G>A p.A947T | Missense Mutation (SNP) | VAF 36/704 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs1554490228; called by muse, mutect2
- HIVEP2 | c.3025G>A p.V1009I | Missense Mutation (SNP) | VAF 226/435 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs766328392; called by muse, mutect2, varscan2
- HJV | c.416G>A p.G139D (on ENST00000336751 / NM_213653.4; = p.G26D on NM_145277.5) | Missense Mutation (SNP) | VAF 32/960 reads (3%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs895693329; called by muse, mutect2
- HMCN1 | c.9527C>T p.T3176I | Missense Mutation (SNP) | VAF 95/277 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54935735; called by muse, varscan2
- HOXA2 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 191/722 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV56065193; called by muse, mutect2, varscan2
- ICA1L | c.1396C>T p.L466F | Missense Mutation (SNP) | VAF 77/427 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763702617; called by muse, mutect2, varscan2
- IGF2R | c.6298G>A p.V2100M | Missense Mutation (SNP) | VAF 135/321 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs758814989; called by muse, mutect2, varscan2
- IGHV1-2 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 216/265 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as rs781877284; called by muse, mutect2, varscan2
- IGHV3-49 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 74/101 reads (73%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as rs781835190; called by muse, mutect2, varscan2
- IGLC7 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 293/692 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.473); catalogued as rs1409787085; called by muse, mutect2, varscan2
- IGSF10 | c.7405C>T p.P2469S | Missense Mutation (SNP) | VAF 26/542 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56400908; called by muse, mutect2
- IGSF3 | c.2234C>T p.A745V (on ENST00000369486 / NM_001007237.3; = p.A765V on NM_001542.4) | Missense Mutation (SNP) | VAF 22/578 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.232); catalogued as COSV59587879; called by muse, mutect2
- IL1R2 | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 88/281 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772421571; called by muse, mutect2, varscan2
- ILDR2 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 137/334 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.617); catalogued as COSV54831353; called by muse, mutect2, varscan2
- INHBA | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 247/957 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV54225839; called by muse, mutect2, varscan2
- INMT | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 303/868 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV50002425; called by muse, varscan2
- IPO7 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as COSV65684242; called by muse, mutect2, varscan2
- IPP | c.1557G>A p.M519I | Missense Mutation (SNP) | VAF 157/389 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV63431870; called by muse, mutect2, varscan2
- IRF7 | c.719G>A p.G240D (on ENST00000397566; = p.G227D on NM_001572.5) | Missense Mutation (SNP) | VAF 32/522 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1162516129; called by muse, mutect2
- KCNJ12 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 275/1301 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100055510; called by muse, mutect2, varscan2
- KCNK4 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 26/480 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1405790645, COSV60454963; called by muse, mutect2
- KIF26B | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 39/860 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as COSV100832007; called by muse, mutect2
- KLC2 | c.1607G>A p.G536D | Missense Mutation (SNP) | VAF 19/387 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.839); catalogued as COSV100270607; called by muse, mutect2
- KLK7 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 22/432 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58344993; called by muse, mutect2
- KRT19 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 302/693 reads (44%) | catalogued as COSV54180650; called by muse, mutect2, varscan2
- KRT38 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 116/387 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1485082863; called by muse, mutect2, varscan2
- KRT77 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 181/410 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs200230736; called by muse, mutect2, varscan2
- LACTB | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 188/410 reads (46%) | catalogued as rs763998435, COSV56055372; called by muse, mutect2, varscan2
- LAMA5 | c.7027G>A p.A2343T | Missense Mutation (SNP) | VAF 22/539 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV53362333; called by muse, mutect2
- LARP1 | c.2579G>A p.G860D (on ENST00000518297 / NM_033551.3; = p.G783D on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/524 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV60426584; called by muse, mutect2
- LCE1E | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 296/570 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV64219908, COSV64220171; called by muse, mutect2, varscan2
- LEXM | c.841G>T p.V281F | Missense Mutation (SNP) | VAF 226/490 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs747586144, COSV64023909; called by muse, varscan2
- LILRA2 | c.998C>T p.T333I | Missense Mutation (SNP) | VAF 122/421 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as rs769487000, COSV52189795; called by muse, mutect2, varscan2
- LMF2 | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 26/711 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1036244501; called by muse, mutect2
- LRP1 | c.2271G>A p.W757* | Nonsense Mutation (SNP) | VAF 28/689 reads (4%) | catalogued as rs1555182964; called by muse, mutect2
- LRP3 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 50/682 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs1249252935; called by muse, mutect2
- LRWD1 | c.1255C>T p.L419F | Missense Mutation (SNP) | VAF 135/775 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52962182; called by muse, mutect2, varscan2
- LY6G6E | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.149); catalogued as rs1431163019; called by muse, mutect2
- LYST | c.9044+1G>A p.X3015_splice | Splice Site (SNP) | VAF 111/304 reads (37%) | catalogued as CS162297; called by muse, mutect2, varscan2
- LZTS3 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 30/770 reads (4%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.992); catalogued as rs1240605097; called by muse, mutect2
- MATN2 | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 118/319 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV54706143; called by muse, mutect2, varscan2
- MCM10 | c.2080G>A p.V694M (on ENST00000484800 / NM_182751.3; = p.V693M on NM_018518.5) | Missense Mutation (SNP) | VAF 26/291 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.732); catalogued as rs1222672502; called by muse, mutect2
- MCRS1 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 29/890 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV57791567; called by muse, mutect2
- MDGA1 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 28/771 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as rs1426870659; called by muse, mutect2
- MEF2B | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 35/723 reads (5%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs1485585407; called by muse, mutect2
- MGAT3 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 321/669 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.769); catalogued as COSV100361953; called by muse, mutect2, varscan2
- MICAL2 | c.4342G>A p.E1448K | Missense Mutation (SNP) | VAF 149/509 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs778452719; called by muse, mutect2, varscan2
- MMP9 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 22/512 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1343892427, COSV63434419; called by muse, mutect2
- MON2 | c.2710C>T p.P904S | Missense Mutation (SNP) | VAF 16/412 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1469028894; called by muse, mutect2
- MORC1 | c.1767+1G>T p.X589_splice | Splice Site (SNP) | VAF 107/256 reads (42%) | catalogued as rs774023589, COSV51713802; called by muse, mutect2, varscan2
- MSH3 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.081); catalogued as rs928378977; ClinVar: uncertain significance; called by muse, mutect2
- MTSS1 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 34/632 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV100274945; called by muse, mutect2
- MUC16 | c.23912C>T p.S7971F | Missense Mutation (SNP) | VAF 26/507 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as COSV67491948; called by muse, mutect2
- MUC17 | c.4318G>A p.A1440T | Missense Mutation (SNP) | VAF 135/614 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs796436659; called by muse, mutect2, varscan2
- MYBPC1 | c.2060G>A p.G687D (on ENST00000550270 / NM_206820.2; = p.G712D on NM_002465.4) | Missense Mutation (SNP) | VAF 20/558 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs971697345; called by muse, mutect2
- MYOCD | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 26/688 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs1259284548; called by muse, mutect2
- NCAN | c.1549G>A p.V517M | Missense Mutation (SNP) | VAF 253/552 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs753329549; called by muse, mutect2, varscan2
- NEK8 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 303/724 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs771928671; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFIX | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 166/308 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV62177631; called by muse, varscan2
- NINL | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 35/786 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1036447484, COSV53998889; called by muse, mutect2
- NLRP10 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 30/698 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1372068484; called by muse, mutect2
- NPIPB15 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 207/876 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.935); catalogued as rs1434321692; called by muse, varscan2
- NRXN3 | c.2842C>T p.P948S (on ENST00000335750 / NM_001330195.2; = p.P575S on NM_004796.6) | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as COSV59748468; called by muse, mutect2
- NUDT9 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 18/454 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV56198115; called by muse, mutect2
- NUP155 | c.3203C>T p.A1068V (on ENST00000231498 / NM_153485.3; = p.A1009V on NM_004298.4) | Missense Mutation (SNP) | VAF 30/532 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.209); catalogued as rs1316739192; called by muse, mutect2
- OBSCN | c.9791C>T p.S3264F | Missense Mutation (SNP) | VAF 197/442 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV52772606; called by muse, mutect2, varscan2
- ODF2 | c.1373T>A p.L458H (on ENST00000434106 / NM_153433.2; = p.L434H on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/327 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV63546808; called by muse, mutect2, varscan2
- OR2AP1 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 28/576 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs1270712567, COSV58725483; called by muse, mutect2
- OR2H2 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 30/845 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1254168371; called by muse, mutect2
- OR2T3 | c.175del p.R59Afs*23 | Frame Shift Del (DEL) | VAF 92/306 reads (30%) | catalogued as COSV62082821; called by mutect2, varscan2
- OR3A2 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 104/350 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs1202718455; called by muse, mutect2, varscan2
- OR4A15 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 163/448 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs374555766, COSV59036488; called by muse, mutect2, varscan2
- OR4E2 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs935739415; called by muse, mutect2
- OR51L1 | c.593G>A p.S198N | Missense Mutation (SNP) | VAF 136/325 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV58624610; called by muse, mutect2, varscan2
- OR56A3 | c.80G>A p.W27* | Nonsense Mutation (SNP) | VAF 272/477 reads (57%) | catalogued as rs112549328; called by muse, mutect2, varscan2
- OR5AS1 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57980880, COSV57981377; called by muse, mutect2
- OTUB1 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 27/397 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55367804; called by muse, mutect2
- PARD3B | c.3310C>T p.L1104F (on ENST00000406610 / NM_001302769.2; = p.L1035F on NM_057177.7) | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.107); catalogued as rs1454255077; called by muse, mutect2
- PCDHA5 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 441/971 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs782323770, COSV65356157; called by muse, mutect2, varscan2
- PCDHB7 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 496/5574 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs782388523, COSV50763014; called by muse, mutect2
- PCDHGB1 | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 472/937 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54022696; called by muse, mutect2, varscan2
- PCF11 | c.2426C>T p.P809L | Missense Mutation (SNP) | VAF 234/443 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs768710624, COSV53536893; called by muse, mutect2, varscan2
- PDE6B | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 263/531 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs545001524; called by muse, mutect2, varscan2
- PHLDB3 | c.1488C>T p.A496= | Splice Region (SNP) | VAF 14/120 reads (12%) | catalogued as rs770788488; called by mutect2, varscan2
- PJA1 | c.1432G>A p.D478N (on ENST00000361478 / NM_145119.4; = p.D290N on NM_022368.5) | Missense Mutation (SNP) | VAF 336/399 reads (84%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as rs765025046; called by muse, mutect2, varscan2
- PKD1 | c.11482G>A p.E3828K (on ENST00000262304 / NM_001009944.3; = p.E3827K on NM_000296.4) | Missense Mutation (SNP) | VAF 32/847 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as CM1210905; called by muse, mutect2
- PKD1 | c.3824G>A p.G1275D | Missense Mutation (SNP) | VAF 259/778 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.309); catalogued as CD1110568, COSV99239195; called by muse, mutect2, varscan2
- PKHD1L1 | c.8198G>A p.S2733N | Missense Mutation (SNP) | VAF 243/558 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs1413275243; called by muse, mutect2, varscan2
- PLEKHA4 | c.812C>T p.T271I | Missense Mutation (SNP) | VAF 27/446 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1229599256; called by muse, mutect2
- PLEKHG6 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 124/396 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as rs765232387; called by muse, varscan2
- POTEA | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.233); catalogued as rs966364912; called by muse, mutect2
- POTEI | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 32/630 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as rs1444964224; called by muse, mutect2
- POU5F2 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 30/680 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV67937689; called by muse, mutect2
- PPP1R13L | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 30/535 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as rs1240720707; called by muse, mutect2
- PRG4 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.493); catalogued as COSV66622868; called by muse, mutect2
- PRMT7 | c.1610G>C p.C537S | Missense Mutation (SNP) | VAF 34/624 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV99545667; called by muse, mutect2
- PRPF38B | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 22/556 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.38); catalogued as rs1213150939; called by muse, mutect2
- PRSS53 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 227/576 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs373736818; called by muse, mutect2, varscan2
- PSG8 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV60613910; called by muse, mutect2, varscan2
- PSMD3 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 28/566 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs1432475361; called by muse, mutect2
- RAB13 | c.542G>A p.G181D | Missense Mutation (SNP) | VAF 114/382 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1184089628; called by muse, mutect2, varscan2
- RAD51C | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 22/500 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1060502603, COSV53627391; ClinVar: uncertain significance; called by muse, mutect2
- RANBP2 | c.1175G>A p.S392N | Missense Mutation (SNP) | VAF 148/314 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.156); catalogued as rs747377255; called by muse, mutect2, varscan2
- RBM3 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.376); catalogued as rs1556989274; called by muse, mutect2
- RBMS3 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 171/349 reads (49%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs757808101, COSV56138582; called by muse, mutect2, varscan2
- RCOR2 | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 69/374 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs565254520; called by muse, mutect2, varscan2
- RNF213 | c.12704G>A p.C4235Y | Missense Mutation (SNP) | VAF 22/564 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.535); catalogued as COSV60408712; called by muse, mutect2
- ROR2 | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 287/644 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as COSV65224069; called by muse, mutect2, varscan2
- RYR2 | c.6431G>A p.R2144H | Missense Mutation (SNP) | VAF 138/283 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as rs1243083109, COSV63666184; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.7546C>T p.L2516F | Missense Mutation (SNP) | VAF 168/418 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs775400701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAP25 | c.146C>T p.S49L (on ENST00000538735; = p.S147L on NM_001168682.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 303/834 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.363); catalogued as rs1265059172; called by muse, mutect2, varscan2
- SCIN | c.260A>G p.D87G | Missense Mutation (SNP) | VAF 119/661 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as rs1027893003; called by muse, mutect2, varscan2
- SCNN1G | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 204/204 reads (100%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.749); catalogued as rs1567263665; called by muse, mutect2, varscan2
- SCUBE1 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 117/297 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99297811; called by muse, mutect2, varscan2
- SCUBE3 | c.743A>G p.D248G | Missense Mutation (SNP) | VAF 222/521 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1469356800; called by muse, mutect2, varscan2
- SELPLG | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 310/746 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as rs781532409; called by muse, mutect2, varscan2
- SETD2 | c.2716C>T p.P906S | Missense Mutation (SNP) | VAF 148/341 reads (43%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs940126759, COSV57438387; called by muse, mutect2, varscan2
- SF3B3 | c.2084G>A p.G695E | Missense Mutation (SNP) | VAF 19/349 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56787109; called by muse, mutect2
- SIGLEC1 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 28/566 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV52460091; called by muse, mutect2
- SKIV2L | c.3671C>T p.A1224V | Missense Mutation (SNP) | VAF 43/1014 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.67); catalogued as rs1480522939; called by muse, mutect2
- SLC17A5 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 27/670 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as rs1485217008, COSV63289074; called by muse, mutect2
- SLC26A3 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 34/952 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100384863; called by muse, mutect2
- SLC2A14 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 21/420 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV100533808; called by muse, mutect2
- SLC35B4 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 28/836 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1410408774; called by muse, mutect2
- SLC35F4 | c.761C>T p.P254L (on ENST00000339762 / NM_001352015.2; = p.P218L on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); catalogued as rs1449122971, COSV100333995, COSV60263686; called by muse, mutect2
- SLC4A3 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 164/453 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.754); catalogued as COSV56093412; called by muse, mutect2, varscan2
- SLC7A8 | c.686C>A p.P229H | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.954); catalogued as rs1457283955; called by muse, mutect2
- SLCO6A1 | c.659G>A p.S220N | Missense Mutation (SNP) | VAF 179/428 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV65814285; called by muse, mutect2, varscan2
- SMU1 | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs1480805784; called by muse, mutect2
- SNAP29 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 36/556 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.09); catalogued as CD052504, COSV53142792; called by muse, mutect2
- SNX22 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 160/328 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs752583321; called by muse, mutect2, varscan2
- SPAG6 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV100509855; called by muse, mutect2
- SPIC | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 26/501 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54691981; called by muse, mutect2
- SPRR2D | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 239/634 reads (38%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.005); catalogued as rs1048273; called by muse, mutect2, varscan2
- STAG2 | c.3067G>A p.E1023K | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as COSV54350602, COSV54376030; called by muse, mutect2, varscan2
- STXBP2 | c.960G>A p.K320= | Splice Region (SNP) | VAF 23/432 reads (5%) | catalogued as COSV55405052; called by muse, mutect2
- SUGT1 | c.932G>A p.R311K (on ENST00000343788 / NM_001130912.3; = p.R279K on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 155/337 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs913870665; called by muse, mutect2, varscan2
- SULT1B1 | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 93/285 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs781611030; called by muse, mutect2, varscan2
- SYNE1 | c.20146G>A p.G6716S (on ENST00000367255 / NM_182961.4; = p.G6645S on NM_033071.3) | Missense Mutation (SNP) | VAF 31/527 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.9); catalogued as rs1450779018; called by muse, mutect2
- SYT12 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 42/668 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV67354479; called by muse, mutect2
- SZT2 | c.9076T>C p.S3026P (on ENST00000634258 / NM_001365999.1; = p.S2969P on NM_015284.4) | Missense Mutation (SNP) | VAF 141/299 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs749473988; called by muse, mutect2, varscan2
- TAS1R3 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 30/875 reads (3%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV59562905; called by muse, mutect2
- TBC1D7 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 160/399 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1339043216; called by muse, mutect2, varscan2
- TBRG1 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 35/495 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1176791032; called by muse, mutect2
- TBX18 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 30/634 reads (5%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.835); catalogued as COSV100858569; called by muse, mutect2
- TCAIM | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 155/360 reads (43%) | catalogued as rs758893977; called by muse, mutect2, varscan2
- TEKT4 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 40/625 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as rs782592018; called by muse, mutect2
- TET2 | c.4147A>G p.R1383G | Missense Mutation (SNP) | VAF 279/501 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54404268; called by muse, mutect2, varscan2
- TEX13A | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 319/352 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61158128; called by muse, mutect2, varscan2
- THAP4 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 32/528 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.027); catalogued as rs1559237098; called by muse, mutect2
- THBS4 | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 28/556 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV63467647; called by muse, mutect2
- TMEM255A | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 29/344 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100434296, COSV58533045; called by muse, mutect2
- TMEM94 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 205/440 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58597863; called by muse, mutect2, varscan2
- TMPRSS9 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 182/323 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs140023303; called by muse, mutect2, varscan2
- TMTC1 | c.1245G>A p.M415I (on ENST00000539277 / NM_001193451.2; = p.M307I on NM_175861.3) | Missense Mutation (SNP) | VAF 97/224 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.212); catalogued as rs1392797419; called by muse, varscan2
- TNF | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 59/1133 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs1454071630; called by muse, mutect2
- TNS1 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 44/657 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1212909557, COSV50690619; called by muse, mutect2
- TNXB | c.10591G>A p.V3531M (on ENST00000647633; = p.V3284M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/910 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs982856078; called by muse, mutect2
- TONSL | c.1175C>T p.T392I | Missense Mutation (SNP) | VAF 200/455 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1219663925; called by muse, mutect2, varscan2
- TRGV5 | c.101G>C p.R34T | Missense Mutation (SNP) | VAF 124/423 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs777086414; called by muse, mutect2, varscan2
- TRIM28 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 30/602 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1330506870; called by muse, mutect2
- TSPYL5 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 263/562 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.305); catalogued as COSV59071342; called by muse, mutect2, varscan2
- TTC6 | c.2668C>T p.L890F | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs1463161390; called by muse, mutect2
- TTN | c.73748C>T p.T24583I (on ENST00000591111; = p.T17159I on NM_003319.4) | Missense Mutation (SNP) | VAF 193/368 reads (52%) | PolyPhen possibly damaging (0.491); catalogued as rs756093359; called by muse, mutect2, varscan2
- TTN | c.52238A>T p.K17413M (on ENST00000591111; = p.K9989M on NM_003319.4) | Missense Mutation (SNP) | VAF 32/516 reads (6%) | PolyPhen probably damaging (0.999); catalogued as COSV59930722; called by muse, mutect2
- TYSND1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 46/522 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs906482815; called by muse, mutect2
- UBLCP1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 85/275 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.018); catalogued as COSV57142540; called by muse, mutect2, varscan2
- UCN3 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 24/347 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as COSV66823933; called by muse, mutect2
- UNC13C | c.3007-1G>A p.X1003_splice | Splice Site (SNP) | VAF 108/228 reads (47%) | catalogued as rs1348916982, COSV52877985; called by muse, mutect2, varscan2
- UNC79 | c.2285G>A p.S762N (on ENST00000393151 / NM_001346218.2; = p.S585N on NM_020818.5) | Missense Mutation (SNP) | VAF 42/535 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as rs1483742641; called by muse, mutect2
- UPK1A | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 17/336 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55877391; called by muse, mutect2
- UPRT | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1381661226; called by muse, mutect2
- URGCP | c.2339G>A p.G780E (on ENST00000453200 / NM_001077663.3; = p.G771E on NM_017920.4) | Missense Mutation (SNP) | VAF 191/592 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1000405676; called by muse, mutect2, varscan2
- USHBP1 | c.1403C>T p.T468I | Missense Mutation (SNP) | VAF 27/444 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as rs1399726029; called by muse, mutect2
- USP21 | c.1375C>T p.L459F | Missense Mutation (SNP) | VAF 22/519 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57091071; called by muse, mutect2
- VPS52 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 46/907 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV71403398; called by muse, mutect2
- WASHC4 | c.3290G>A p.S1097N | Missense Mutation (SNP) | VAF 138/376 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1314751000; called by muse, mutect2, varscan2
- WDR83OS | c.252C>T p.F84= | Splice Region (SNP) | VAF 121/197 reads (61%) | catalogued as rs1299826627; called by muse, mutect2, varscan2
- WIPF1 | c.1166G>A p.G389D | Missense Mutation (SNP) | VAF 20/386 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1234920633, COSV99768474; called by muse, mutect2
- WIZ | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 34/570 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.063); catalogued as COSV54611498; called by muse, mutect2
- ZBTB1 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as rs1034834331; called by muse, mutect2
- ZCCHC2 | c.1796A>G p.N599S | Missense Mutation (SNP) | VAF 142/338 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs935694279; called by muse, mutect2, varscan2
- ZCCHC2 | c.2699T>C p.V900A | Missense Mutation (SNP) | VAF 210/516 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as rs768507813; called by muse, mutect2, varscan2
- ZER1 | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 32/570 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as COSV99402357; called by muse, mutect2
- ZNF469 | c.9413G>A p.R3138K (on ENST00000437464; = p.R3166K on NM_001367624.2) | Missense Mutation (SNP) | VAF 48/882 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1042617748; called by muse, mutect2
- ZNF48 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 31/706 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV60783681; called by muse, mutect2
- ZNF644 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV100494476; called by muse, mutect2
- ZSWIM6 | c.3632G>A p.R1211Q | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs896708412; called by muse, mutect2, varscan2
- ABCA12 | c.2383C>T p.P795S (on ENST00000272895 / NM_173076.3; = p.P477S on NM_015657.3) | Missense Mutation (SNP) | VAF 160/345 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ABCA13 | c.14761G>A p.A4921T | Missense Mutation (SNP) | VAF 17/388 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2
- ABCA8 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 172/383 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ABCC10 | c.1608G>A p.K536= (on ENST00000372530 / NM_001198934.2; = p.K493= on NM_033450.2 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 124/265 reads (47%) | called by muse, mutect2, varscan2
- ABCC4 | c.3184A>G p.T1062A | Missense Mutation (SNP) | VAF 153/381 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ABCC6 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 340/762 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ABHD13 | c.781C>T p.L261F | Missense Mutation (SNP) | VAF 132/367 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC099489.1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 33/721 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.085); called by muse, mutect2
- ACAA2 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 18/343 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACO2 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 277/667 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACOT2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 47/632 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.218); called by muse, mutect2
- ACTN3 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 30/520 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.763); called by muse, mutect2
- ADAM30 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 21/460 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADAMTS10 | c.2241C>T p.A747= | Splice Region (SNP) | VAF 180/309 reads (58%) | called by muse, mutect2, varscan2
- ADAMTS17 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2
- ADAMTS6 | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 131/288 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ADAMTSL3 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 152/357 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADARB1 | c.1835C>T p.P612L (on ENST00000360697 / NM_001346687.2; = p.P572L on NM_001112.4) | Missense Mutation (SNP) | VAF 28/524 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ADGRF5 | c.2329C>T p.L777F | Missense Mutation (SNP) | VAF 192/396 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADPRM | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.175); called by muse, mutect2
- ADRA1B | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 289/624 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AHNAK | c.15145G>A p.G5049S | Missense Mutation (SNP) | VAF 34/560 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.209); called by muse, mutect2
- AL162417.1 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 22/528 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.079); called by muse, mutect2
- AL451007.3 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 54/881 reads (6%) | called by muse, mutect2
- AL645922.1 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 324/706 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALK | c.3010G>A p.V1004I | Missense Mutation (SNP) | VAF 34/609 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- ALKBH8 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALX1 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 28/640 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.092); called by muse, mutect2
- AMPH | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 84/541 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ANGPTL5 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- ANK2 | c.10534G>A p.E3512K | Missense Mutation (SNP) | VAF 26/545 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANKMY1 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 122/489 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD17 | c.5188G>A p.V1730I | Missense Mutation (SNP) | VAF 101/239 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- ANKRD60 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 119/304 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO8 | c.2836G>A p.A946T | Missense Mutation (SNP) | VAF 55/720 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- APAF1 | c.1681C>T p.P561S (on ENST00000551964 / NM_181861.2; = p.P550S on NM_001160.3) | Missense Mutation (SNP) | VAF 22/539 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- APOA4 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 243/465 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- AQP6 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 43/918 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARFRP1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 23/530 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP10 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 24/638 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- ARHGAP9 | c.2083G>A p.V695M (on ENST00000393797 / NM_001319850.2; = p.V676M on NM_032496.4) | Missense Mutation (SNP) | VAF 137/298 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF17 | c.5050G>A p.E1684K | Missense Mutation (SNP) | VAF 42/702 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- ARHGEF17 | c.5699C>T p.T1900I | Missense Mutation (SNP) | VAF 15/379 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2
- ARMC6 | c.1428G>T p.K476N (on ENST00000392336; = p.K451N on NM_033415.4) | Missense Mutation (SNP) | VAF 104/451 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- ARSK | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 126/412 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ASXL3 | c.2255C>T p.T752I | Missense Mutation (SNP) | VAF 36/585 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2
- ATAD2 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2
- ATG2B | c.5897C>T p.T1966I | Missense Mutation (SNP) | VAF 127/196 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- ATG2B | c.2177C>T p.T726I | Missense Mutation (SNP) | VAF 117/163 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ATIC | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 95/485 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ATP13A2 | c.2090C>T p.T697I | Missense Mutation (SNP) | VAF 30/785 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2
- ATP2A1 | c.1547G>A p.G516D | Missense Mutation (SNP) | VAF 19/367 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ATP9B | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 41/747 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATXN1L | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 41/825 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- AUNIP | c.161G>A p.R54K | Missense Mutation (SNP) | VAF 113/365 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- B3GNT7 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 46/772 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.027); called by muse, mutect2
- BIRC3 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2
- BPNT2 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 109/264 reads (41%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- BSG | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 21/455 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.055); called by muse, mutect2
- BTBD9 | c.1318G>A p.V440I | Missense Mutation (SNP) | VAF 187/389 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- C11orf42 | c.879G>A p.W293* | Nonsense Mutation (SNP) | VAF 28/397 reads (7%) | called by muse, mutect2
- C16orf71 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 165/427 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2
- C17orf97 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 16/418 reads (4%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.015); called by muse, mutect2
- C1QL4 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 36/886 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.037); called by muse, mutect2
- C6orf47 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 56/1140 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- C6orf58 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 187/449 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CA7 | c.623G>A p.S208N | Missense Mutation (SNP) | VAF 204/513 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CACNA1I | c.3794C>T p.A1265V | Missense Mutation (SNP) | VAF 32/779 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CARD10 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 37/877 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CASKIN2 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 31/738 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- CBFA2T2 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 382/699 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CBLC | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- CBLL2 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 11/261 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, mutect2
- CCDC150 | c.2311C>T p.L771F | Missense Mutation (SNP) | VAF 123/278 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC189 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 25/668 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.442); called by muse, mutect2
- CCDC61 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- CCDC88C | c.2156C>T p.T719I | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2
- CCDC88C | c.1112C>T p.T371I | Missense Mutation (SNP) | VAF 188/301 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CCDC97 | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 36/552 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2
- CCNB1 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 130/252 reads (52%) | called by muse, mutect2, varscan2
- CD8B2 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 24/589 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.104); called by muse, mutect2
- CDC25A | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 24/543 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.224); called by muse, mutect2
- CDC40 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 21/448 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.388); called by muse, mutect2
- CDCP2 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 156/417 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CDH13 | c.366G>A p.Q122= | Splice Region (SNP) | VAF 20/276 reads (7%) | called by muse, mutect2
- CDH17 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 29/524 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- CDH2 | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 27/486 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2
- CDH4 | c.1892T>C p.I631T | Missense Mutation (SNP) | VAF 252/742 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); called by muse, varscan2
- CDK19 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 41/862 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); called by muse, mutect2
- CDK5R2 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 28/684 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDK6 | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 142/420 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- CDR1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 20/363 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- CEACAM4 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 101/374 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CELF4 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.313); called by muse, mutect2
- CELSR1 | c.7088+1G>A p.X2363_splice | Splice Site (SNP) | VAF 30/543 reads (6%) | called by muse, mutect2
- CEMIP | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 29/604 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- CENPC | c.1559G>A p.S520N | Missense Mutation (SNP) | VAF 25/588 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- CEP290 | c.4948G>A p.D1650N | Missense Mutation (SNP) | VAF 129/369 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- CFAP46 | c.6229G>A p.D2077N | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); called by muse, mutect2
- CFAP47 | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.02); called by muse, mutect2
- CHD1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 18/418 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- CHD1L | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 22/506 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- CHD4 | c.2963G>A p.G988D (on ENST00000357008 / NM_001363606.2; = p.G1001D on NM_001273.5) | Missense Mutation (SNP) | VAF 169/423 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD5 | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 43/988 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.346); called by muse, mutect2
- CHD5 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 26/522 reads (5%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2
- CHD6 | c.2939A>G p.D980G | Missense Mutation (SNP) | VAF 278/531 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CHD7 | c.6325G>A p.V2109I | Missense Mutation (SNP) | VAF 35/528 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.235); called by muse, mutect2
- CHD7 | c.6413G>A p.G2138D | Missense Mutation (SNP) | VAF 172/388 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CHMP3 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.918); called by muse, mutect2
- CHRD | c.2068C>A p.P690T | Missense Mutation (SNP) | VAF 400/927 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- CKAP5 | c.5599C>T p.P1867S (on ENST00000529230 / NM_001008938.4; = p.P1807S on NM_014756.3) | Missense Mutation (SNP) | VAF 34/414 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- CLCN4 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 30/363 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLDN5 | c.530G>A p.G177D (on ENST00000618236 / NM_001363066.2; = p.G262D on NM_003277.4) | Missense Mutation (SNP) | VAF 39/760 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLIC3 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 34/712 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); called by muse, mutect2
- CLPTM1 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 25/547 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- CMTM4 | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNKSR1 | c.1934G>A p.G645D (on ENST00000374253 / NM_001297647.2; = p.G638D on NM_006314.3) | Missense Mutation (SNP) | VAF 237/558 reads (42%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNNM4 | c.2107C>T p.L703F | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CNOT6L | c.1501C>T p.L501F (on ENST00000504123 / NM_001286790.2; = p.L496F on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); called by muse, mutect2
- COG1 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 21/425 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- COL11A2 | c.3422G>A p.G1141D (on ENST00000341947 / NM_080680.3; = p.G1034D on NM_080679.2) | Missense Mutation (SNP) | VAF 217/661 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL16A1 | c.4595G>A p.G1532D | Missense Mutation (SNP) | VAF 19/420 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL4A4 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 104/223 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL5A3 | c.4093C>T p.P1365S | Missense Mutation (SNP) | VAF 23/429 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.063); called by muse, mutect2
- COL5A3 | c.3749G>A p.G1250E | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COLGALT1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 42/594 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.017); called by muse, mutect2
- CP | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.046); called by muse, mutect2
- CPEB4 | c.2140G>A p.V714M | Missense Mutation (SNP) | VAF 30/646 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2
- CPLANE1 | c.274G>A p.V92I (on ENST00000425232; = p.V164I on NM_023073.3) | Missense Mutation (SNP) | VAF 119/310 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CPOX | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 428/827 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CPSF1 | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 32/728 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- CRACR2A | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 240/590 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, varscan2
- CROT | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 16/313 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); called by muse, mutect2
- CSMD1 | c.9818C>T p.P3273L (on ENST00000520002; = p.P3272L on NM_033225.6) | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- CTNND1 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 26/439 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.091); called by muse, mutect2
- CTRB2 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 26/644 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.279); called by muse, mutect2
- CTTNBP2 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 39/854 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.143); called by muse, mutect2
- CYP17A1 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 23/256 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.024); called by muse, mutect2
- CYP21A2 | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 40/771 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2
- DAAM2 | c.1777C>T p.L593F | Missense Mutation (SNP) | VAF 30/730 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, mutect2
- DAG1 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 22/612 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- DARS2 | c.1917_1927del p.K640Sfs*12 | Frame Shift Del (DEL) | VAF 116/273 reads (42%) | called by mutect2, pindel, varscan2
- DBX1 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 44/615 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2
- DCBLD2 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- DCTN4 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 150/399 reads (38%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- DEAF1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 22/520 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.173); called by muse, mutect2
- DEAF1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 28/480 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2
- DGKQ | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 32/846 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); called by muse, mutect2
- DHX16 | c.2168C>T p.A723V | Missense Mutation (SNP) | VAF 26/698 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- DIDO1 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 39/826 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DLGAP4 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 41/814 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.18); called by muse, mutect2
- DLX6 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 31/1072 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.132); called by muse, mutect2
- DMBT1 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 30/323 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- DMD | c.6988C>T p.L2330F | Missense Mutation (SNP) | VAF 25/286 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- DMGDH | c.276+1G>A p.X92_splice | Splice Site (SNP) | VAF 22/401 reads (5%) | called by muse, mutect2
- DNA2 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.357); called by muse, mutect2
- DNAAF1 | c.868T>C p.C290R | Missense Mutation (SNP) | VAF 81/244 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- DNAAF2 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.082); called by muse, mutect2
- DNAAF4 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 107/221 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- DNAH3 | c.11948A>G p.Y3983C | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DNAH6 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2
- DNMBP | c.3235C>T p.Q1079* | Nonsense Mutation (SNP) | VAF 16/250 reads (6%) | called by muse, mutect2
- DOCK11 | c.1177-1G>A p.X393_splice | Splice Site (SNP) | VAF 126/137 reads (92%) | called by muse, mutect2, varscan2
- DOCK5 | c.5413T>C p.S1805P | Missense Mutation (SNP) | VAF 186/409 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- DZANK1 | c.1861G>A p.V621I (on ENST00000262547 / NM_001099407.1; = p.V428I on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/432 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- EFR3B | c.2278G>A p.A760T | Missense Mutation (SNP) | VAF 30/448 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); called by muse, mutect2
- EHMT2 | c.3232G>A p.D1078N | Missense Mutation (SNP) | VAF 240/559 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ELP2 | c.1802C>T p.T601I | Missense Mutation (SNP) | VAF 15/327 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); called by muse, mutect2
- ELP3 | c.909G>A p.E303= | Splice Region (SNP) | VAF 118/285 reads (41%) | called by muse, mutect2, varscan2
- EMC1 | c.1609G>A p.V537M | Missense Mutation (SNP) | VAF 19/430 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- ENPP1 | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 26/407 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ERMAP | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 29/446 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2
- ESF1 | c.2102T>G p.I701R | Missense Mutation (SNP) | VAF 108/293 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ESPNL | c.2806G>A p.D936N | Missense Mutation (SNP) | VAF 39/722 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ETFRF1 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 85/203 reads (42%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EXOC2 | c.295+1G>A p.X99_splice | Splice Site (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- FAM126A | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 126/543 reads (23%) | called by muse, mutect2, varscan2
- FAM151A | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 26/555 reads (5%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- FAM186A | c.6849G>A p.R2283= | Splice Region (SNP) | VAF 21/350 reads (6%) | called by muse, mutect2
- FAM205C | c.795G>A p.W265* | Nonsense Mutation (SNP) | VAF 21/263 reads (8%) | called by muse, mutect2
- FAN1 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 38/763 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.05); called by muse, mutect2
- FASTKD2 | c.174G>A p.W58* | Nonsense Mutation (SNP) | VAF 15/334 reads (4%) | called by muse, mutect2
- FAT3 | c.3379C>T p.P1127S | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBLN2 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 50/887 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2
- FCSK | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 45/714 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); called by muse, mutect2
- FECH | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 19/366 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FGF10 | c.325+1G>T p.X109_splice | Splice Site (SNP) | VAF 142/299 reads (47%) | called by muse, mutect2, varscan2
- FHAD1 | c.2618C>T p.A873V | Missense Mutation (SNP) | VAF 25/582 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.162); called by muse, mutect2
- FHOD3 | c.2357A>G p.Y786C (on ENST00000359247 / NM_001281739.3; = p.Y803C on NM_025135.5) | Missense Mutation (SNP) | VAF 266/533 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FKBP3 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2
- FLRT1 | c.1060G>A p.G354S | Missense Mutation (SNP) | VAF 43/676 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FLRT2 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); called by muse, mutect2
- FLVCR2 | c.937C>T p.L313F | Missense Mutation (SNP) | VAF 17/241 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- FOXB2 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 32/863 reads (4%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.112); called by muse, mutect2
- FOXF1 | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 232/712 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.014); called by muse, varscan2
- FRG2 | c.581G>A p.W194* | Nonsense Mutation (SNP) | VAF 250/547 reads (46%) | called by muse, mutect2, varscan2
- FRMPD3 | c.5128G>A p.V1710M | Missense Mutation (SNP) | VAF 25/359 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- FTHL17 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 30/518 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.254); called by muse, mutect2
- FUBP3 | c.1421G>A p.S474N | Missense Mutation (SNP) | VAF 24/606 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2
- FXYD5 | c.413-1G>A p.X138_splice | Splice Site (SNP) | VAF 138/447 reads (31%) | called by muse, mutect2, varscan2
- FZD7 | c.1328G>A p.G443D | Missense Mutation (SNP) | VAF 30/610 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GABRA3 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 252/295 reads (85%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GALNT17 | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 198/759 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- GALNT5 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 90/322 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNTL6 | c.1747A>G p.I583V | Missense Mutation (SNP) | VAF 27/645 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- GATAD2A | c.1575G>A p.Q525= | Splice Region (SNP) | VAF 31/372 reads (8%) | called by muse, mutect2
- GCC2 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- GCN1 | c.729+1G>A p.X243_splice | Splice Site (SNP) | VAF 147/315 reads (47%) | called by muse, mutect2, varscan2
- GIMD1 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 33/665 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- GLI1 | c.36C>A p.S12R | Missense Mutation (SNP) | VAF 195/598 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- GLT6D1 | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 25/530 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2
- GNAZ | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 36/589 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2
- GNL1 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 34/738 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2
- GOLGA5 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); called by muse, mutect2
- GOLGB1 | c.8984C>T p.S2995F | Missense Mutation (SNP) | VAF 107/275 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- GORAB | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 186/461 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GP5 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 310/845 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- GPATCH8 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 148/353 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GPHB5 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GPR1 | c.872G>A p.G291D | Missense Mutation (SNP) | VAF 21/486 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); called by muse, mutect2
- GPR179 | c.1196G>A p.S399N (on ENST00000621958; = p.S398N on NM_001004334.4) | Missense Mutation (SNP) | VAF 32/758 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2
- GPR85 | c.74C>T p.T25I | Missense Mutation (SNP) | VAF 157/640 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- GRIK5 | c.2891C>T p.P964L | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRIN3B | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 142/514 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GSG1L2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 38/706 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.035); called by muse, mutect2
- GTPBP1 | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 176/398 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HBQ1 | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 28/540 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HCN4 | c.3014C>A p.S1005Y | Missense Mutation (SNP) | VAF 412/888 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC6 | c.756G>A p.W252* | Nonsense Mutation (SNP) | VAF 17/356 reads (5%) | called by muse, mutect2
- HECTD4 | c.10393G>A p.D3465N | Missense Mutation (SNP) | VAF 42/776 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.339); called by muse, mutect2
- HEPH | c.3116C>T p.P1039L (on ENST00000343002; = p.P772L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/438 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2
- HERC4 | c.2456C>T p.A819V (on ENST00000395198 / NM_022079.3; = p.A811V on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.889); called by muse, mutect2
- HGS | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 217/522 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- HIF1A | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); called by muse, mutect2
- HLX | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 362/839 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HMG20B | c.942-1G>A p.X314_splice | Splice Site (SNP) | VAF 246/536 reads (46%) | called by muse, mutect2, varscan2
- HNRNPUL1 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 25/629 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- HOMEZ | c.20G>A p.S7N | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.001); called by muse, mutect2
- HOXA1 | c.99G>T p.R33S | Missense Mutation (SNP) | VAF 228/808 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, varscan2
- HOXA2 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 23/669 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.061); called by muse, mutect2
- HOXD11 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 33/528 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- HR | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 244/610 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- HS2ST1 | c.970T>C p.F324L | Missense Mutation (SNP) | VAF 18/418 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HSPBAP1 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 32/784 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2
- HTR6 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 299/766 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- HTRA3 | c.1283C>T p.T428I | Missense Mutation (SNP) | VAF 256/611 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- IFNK | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.028); called by muse, mutect2
- IGF1 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 26/530 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.232); called by muse, mutect2
- IGF2BP1 | c.1100G>A p.G367D | Missense Mutation (SNP) | VAF 21/435 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- IHH | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 36/630 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2
- IL1R1 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 16/371 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.309); called by muse, mutect2
- IL27RA | c.1694G>A p.S565N | Missense Mutation (SNP) | VAF 185/287 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- INPP4B | c.1390C>T p.Q464* | Nonsense Mutation (SNP) | VAF 151/375 reads (40%) | called by muse, mutect2, varscan2
- IQCA1 | c.1210+1G>A p.X404_splice | Splice Site (SNP) | VAF 23/406 reads (6%) | called by muse, mutect2
- IQCJ-SCHIP1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 30/662 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IRAK2 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 26/576 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- IRF4 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 42/740 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2
- ITGA7 | c.845A>T p.Q282L (on ENST00000555728; = p.Q238L on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/472 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ITPKB | c.1631G>A p.S544N | Missense Mutation (SNP) | VAF 211/600 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- JUNB | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 122/585 reads (21%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- JUP | c.1734G>A p.M578I | Missense Mutation (SNP) | VAF 153/430 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- KAT14 | c.2239C>T p.Q747* | Nonsense Mutation (SNP) | VAF 214/499 reads (43%) | called by muse, mutect2, varscan2
- KATNAL1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 19/510 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- KCNG2 | c.386A>G p.E129G | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- KCNG3 | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 25/474 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- KCNS3 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 296/553 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KDM4C | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 27/574 reads (5%) | called by muse, mutect2
- KDM6B | c.2759C>G p.A920G | Missense Mutation (SNP) | VAF 265/588 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KDM6B | c.3145G>A p.A1049T | Missense Mutation (SNP) | VAF 38/1024 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2
- KDR | c.1172G>A p.R391K | Missense Mutation (SNP) | VAF 28/618 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KIAA0100 | c.5618G>A p.S1873N | Missense Mutation (SNP) | VAF 150/317 reads (47%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIAA1522 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 32/703 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); called by muse, mutect2
- KIAA2012 | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 24/467 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2
- KIF1C | c.2438G>A p.G813D | Missense Mutation (SNP) | VAF 48/812 reads (6%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.029); called by muse, mutect2
- KIFC3 | c.2201G>A p.S734N | Missense Mutation (SNP) | VAF 22/480 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2
- KIRREL3 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 102/340 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLHDC4 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 28/722 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2
- KMT5B | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 17/310 reads (5%) | called by muse, mutect2
- KRI1 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 22/378 reads (6%) | called by muse, mutect2
- KRT72 | c.1195G>C p.A399P | Missense Mutation (SNP) | VAF 40/623 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- KRTAP5-1 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 32/504 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.808); called by muse, mutect2
- KRTAP9-9 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 33/772 reads (4%) | SIFT tolerated (0.73); called by muse, mutect2
- KSR2 | c.1786G>A p.V596M | Missense Mutation (SNP) | VAF 228/557 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- LAMB2 | c.1379G>A p.S460N | Missense Mutation (SNP) | VAF 28/538 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); called by muse, mutect2
- LAMC2 | c.2611G>A p.A871T | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- LCTL | c.494_497del p.K165Tfs*7 | Frame Shift Del (DEL) | VAF 143/296 reads (48%) | called by mutect2, pindel, varscan2
- LEF1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 150/341 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- LEMD3 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 27/606 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- LGALSL | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 26/520 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- LILRB5 | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 98/375 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- LIMK1 | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 42/1084 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.258); called by muse, mutect2
- LMBR1 | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 25/586 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2
- LRFN3 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 115/448 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- LRIF1 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 18/411 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRRC37A | c.3583G>A p.A1195T | Missense Mutation (SNP) | VAF 37/570 reads (6%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.956); called by muse, mutect2
- LRRK2 | c.4043C>T p.T1348I | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- LRRTM2 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 30/564 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRWD1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 34/706 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.307); called by muse, mutect2
- LSR | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 76/384 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- LTBP1 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 32/751 reads (4%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- M6PR | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- MAGI2 | c.3457G>A p.G1153R | Missense Mutation (SNP) | VAF 183/533 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MAK16 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 28/586 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.026); called by muse, mutect2
- MAP2 | c.3317G>A p.S1106N | Missense Mutation (SNP) | VAF 24/430 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2
- MAP3K9 | c.3148C>T p.P1050S (on ENST00000554752 / NM_001284230.1; = p.P1064S on NM_033141.4) | Missense Mutation (SNP) | VAF 39/466 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2
- MAP4K1 | c.2495G>A p.G832D | Missense Mutation (SNP) | VAF 17/341 reads (5%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- MCM5 | c.2197C>T p.L733F | Missense Mutation (SNP) | VAF 27/532 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2
- MDC1 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 30/804 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MED13L | c.6355C>T p.Q2119* | Nonsense Mutation (SNP) | VAF 20/506 reads (4%) | called by muse, mutect2
- MED20 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 143/332 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- METTL22 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 130/432 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- MGA | c.5186G>A p.G1729E | Missense Mutation (SNP) | VAF 126/297 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- MGA | c.7191G>A p.K2397= (on ENST00000219905 / NM_001164273.1; = p.K2188= on NM_001080541.2) | Splice Region (SNP) | VAF 19/366 reads (5%) | called by muse, mutect2
- MIEN1 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 28/765 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- MLC1 | c.496T>C p.S166P | Missense Mutation (SNP) | VAF 181/413 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MLN | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 169/497 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 233/505 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MPEG1 | c.1978G>A p.V660I | Missense Mutation (SNP) | VAF 47/635 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.019); called by muse, mutect2
- MPEG1 | c.1750A>G p.T584A | Missense Mutation (SNP) | VAF 42/499 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- MROH7 | c.3703G>A p.E1235K | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2
- MRPS31 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 109/314 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- MS4A14 | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 23/447 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- MS4A15 | c.323G>A p.G108D (on ENST00000405633 / NM_001098835.2; = p.G15D on NM_152717.3) | Missense Mutation (SNP) | VAF 20/496 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MS4A18 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 33/496 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.435); called by muse, mutect2
- MSTN | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 18/418 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- MTHFR | c.418G>A p.G140S | Missense Mutation (SNP) | VAF 28/546 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2
- MTMR14 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 30/676 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.033); called by muse, mutect2
- MTUS1 | c.3631G>A p.E1211K (on ENST00000262102 / NM_001363061.1; = p.E377K on NM_020749.4) | Missense Mutation (SNP) | VAF 130/323 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MUC16 | c.32551C>T p.P10851S | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.556); called by muse, mutect2
- MUC22 | c.2135G>A p.G712D | Missense Mutation (SNP) | VAF 41/992 reads (4%) | SIFT tolerated (0.06); called by muse, mutect2
- MUC6 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 24/516 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.711); called by muse, mutect2
- MYO9B | c.5060G>A p.R1687K | Missense Mutation (SNP) | VAF 161/280 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NAA25 | c.553G>A p.V185M | Missense Mutation (SNP) | VAF 20/443 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- NAPSA | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 18/397 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.36); called by muse, mutect2
- NAT10 | c.2563G>A p.G855R | Missense Mutation (SNP) | VAF 22/462 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.133); called by muse, mutect2
- NAV1 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NBEA | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 161/382 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NCF2 | c.451A>C p.K151Q | Missense Mutation (SNP) | VAF 56/528 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- NDEL1 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 112/315 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDN | c.362T>A p.F121Y | Missense Mutation (SNP) | VAF 167/462 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- NEB | c.446A>G p.H149R | Missense Mutation (SNP) | VAF 27/534 reads (5%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.987); called by muse, mutect2
- NEDD4L | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 33/576 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.077); called by muse, mutect2
- NEDD9 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 244/512 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NEFL | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 355/726 reads (49%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- NEFM | c.2294G>A p.G765E | Missense Mutation (SNP) | VAF 265/589 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEK11 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 198/440 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- NF1 | c.7131del p.F2377Lfs*19 (on ENST00000358273 / NM_001042492.3; = p.F2356Lfs*19 on NM_000267.3) | Frame Shift Del (DEL) | VAF 225/518 reads (43%) | called by mutect2, pindel, varscan2
- NF2 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 102/282 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- NFATC4 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 302/395 reads (76%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- NFE2L3 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 109/546 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NFIC | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 54/711 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.346); called by muse, mutect2
- NFKBIL1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 40/1116 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2
- NFX1 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 27/244 reads (11%) | called by muse, mutect2, varscan2
- NKG7 | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.405); called by muse, mutect2
- NKIRAS2 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 28/514 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.013); called by muse, mutect2
- NLRC3 | c.1879G>A p.G627S | Missense Mutation (SNP) | VAF 31/652 reads (5%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2
- NLRP12 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.039); called by muse, mutect2
- NLRP7 | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 347/622 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- NMUR1 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 30/646 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- NOCT | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 47/782 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2
- NOL10 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 27/354 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- NPM2 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 22/548 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.156); called by muse, mutect2
- NPY5R | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 200/433 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRDC | c.765G>A p.R255= | Splice Region (SNP) | VAF 132/402 reads (33%) | called by muse, mutect2, varscan2
- NRP2 | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 164/333 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NRXN1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2
- NRXN2 | c.851G>A p.G284D | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.389); called by muse, mutect2
- NTN3 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 359/849 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUMB | c.1009G>A p.A337T (on ENST00000355058; = p.A326T on NM_003744.5) | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2
- NUP160 | c.4066G>C p.E1356Q | Missense Mutation (SNP) | VAF 91/276 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- NUP35 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 80/268 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- NUP62 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 20/457 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- NUP85 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 16/398 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- NXN | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 26/522 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- OCM2 | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 28/739 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- ODC1 | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- OGFRL1 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 153/358 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- OMD | c.509G>A p.G170D | Missense Mutation (SNP) | VAF 22/486 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2
- OPLAH | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 312/699 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR14J1 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 220/529 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR14K1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 187/430 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OR2F1 | c.692G>A p.R231K | Missense Mutation (SNP) | VAF 28/697 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- OR56A4 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 97/478 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR5T1 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 23/587 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); called by muse, mutect2
- OR9G4 | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 52/606 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.282); called by muse, mutect2
- OTP | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 23/519 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PAK1IP1 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 22/522 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.777); called by muse, mutect2
- PAN2 | c.2958G>A p.E986= (on ENST00000425394 / NM_001127460.3; = p.E982= on NM_014871.5) | Splice Region (SNP) | VAF 18/394 reads (5%) | called by muse, mutect2
- PARD6G | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 42/894 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PARP10 | c.2552_2553del p.V851Afs*15 | Frame Shift Del (DEL) | VAF 217/570 reads (38%) | called by mutect2, pindel, varscan2
- PATE2 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 17/322 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); called by muse, mutect2
- PAX9 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 30/337 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAXIP1 | c.1798+1G>A p.X600_splice | Splice Site (SNP) | VAF 79/402 reads (20%) | called by muse, varscan2
- PCDH12 | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 28/720 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.104); called by muse, mutect2
- PCDHAC2 | c.2359C>T p.L787F | Missense Mutation (SNP) | VAF 28/642 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); called by muse, mutect2
- PCDHB4 | c.1851G>A p.W617* | Nonsense Mutation (SNP) | VAF 43/1225 reads (4%) | called by muse, mutect2
- PCLO | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 264/938 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); called by muse, mutect2
- PDE11A | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 33/595 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2
- PDE2A | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 36/622 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); called by muse, mutect2
- PDE4D | c.2099C>T p.T700I (on ENST00000340635 / NM_001104631.2; = p.T564I on NM_006203.4) | Missense Mutation (SNP) | VAF 23/503 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PDK3 | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- PEG3 | c.4457G>A p.G1486E | Missense Mutation (SNP) | VAF 20/543 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.36); called by muse, mutect2
- PELP1 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 150/368 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- PGM2L1 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 19/415 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.067); called by muse, mutect2
- PGP | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 348/817 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PHLDB1 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 23/693 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- PIANP | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 32/768 reads (4%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2
- PIDD1 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 45/931 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.076); called by muse, mutect2
- PIK3C2A | c.1848+1G>A p.X616_splice | Splice Site (SNP) | VAF 20/242 reads (8%) | called by muse, mutect2
- PIK3CB | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 186/438 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PIK3IP1 | c.38A>T p.N13I | Missense Mutation (SNP) | VAF 165/567 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- PIKFYVE | c.4561C>T p.P1521S | Missense Mutation (SNP) | VAF 18/267 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.272); called by muse, mutect2
- PIMREG | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 179/413 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PITX1 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 36/804 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2
- PKD1 | c.4225C>T p.P1409S | Missense Mutation (SNP) | VAF 46/868 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.021); called by muse, mutect2
- PKN3 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 40/896 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLAAT5 | c.371_375+5del p.X124_splice | Splice Site (DEL) | VAF 38/156 reads (24%) | called by mutect2, pindel, varscan2
- PLEC | c.4570G>A p.E1524K (on ENST00000322810 / NM_201380.4; = p.E1414K on NM_000445.5) | Missense Mutation (SNP) | VAF 45/1122 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2
- PLEKHG4B | c.2453G>A p.R818K (on ENST00000283426; = p.R1174K on NM_052909.5) | Missense Mutation (SNP) | VAF 38/614 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2
- PLK1 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.044); called by muse, mutect2
- PNISR | c.1901G>A p.S634N | Missense Mutation (SNP) | VAF 142/371 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- POLA2 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2
- POLE | c.2872G>A p.V958M | Missense Mutation (SNP) | VAF 128/321 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLR1G | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 24/542 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.179); called by muse, mutect2
- POLR3F | c.773G>A p.G258D | Missense Mutation (SNP) | VAF 168/501 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- POTED | c.920C>T p.T307I | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2
- PPM1G | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 40/496 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- PPP1R14C | c.485A>C p.K162T | Missense Mutation (SNP) | VAF 187/379 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PPP1R15A | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 22/471 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.382); called by muse, mutect2
- PPP2R5C | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 26/351 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2
- PPRC1 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 246/275 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- PRDM16 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 48/969 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.088); called by muse, mutect2
- PRDM2 | c.4843G>A p.V1615I | Missense Mutation (SNP) | VAF 219/472 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRICKLE2 | c.2447C>T p.A816V (on ENST00000295902; = p.A760V on NM_198859.4) | Missense Mutation (SNP) | VAF 26/729 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.396); called by muse, mutect2
- PRKCG | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 28/371 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- PRMT6 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 30/722 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- PROS1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 26/518 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2
- PRPF38A | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 109/274 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PRR12 | c.3434G>A p.G1145E (on ENST00000615927; = p.G1966E on NM_020719.3) | Missense Mutation (SNP) | VAF 20/406 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.058); called by muse, mutect2
- PRR33 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 32/604 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2
- PRRT2 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 36/748 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.458); called by muse, mutect2
- PSMB8 | c.775G>A p.V259I (on ENST00000374882 / NM_148919.4; = p.V255I on NM_004159.5) | Missense Mutation (SNP) | VAF 195/476 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PSMD12 | c.1246del p.Q416Rfs*10 | Frame Shift Del (DEL) | VAF 177/446 reads (40%) | called by mutect2, pindel, varscan2
- PSPN | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 38/632 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.382); called by muse, mutect2
811 further variants in this file (223 protein-altering or splice-affecting, 517 silent, 71 other) are not listed here.
